Somatic mutation profile of tumor specimen 0DTYBA from CCDI case PBCKIK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 1.1 years (417 days).
Specimen 0DTYBA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce4004d1-8533-4b60-88fa-66816cfb679a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTYAZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f3b1a36-d638-4333-8101-5fb9009bf1e7

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: RNA 1, Nonsense Mutation 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NLRP5 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 52/458 reads (11%) | catalogued as rs1419853541, COSV66764077; called by muse, mutect2, varscan2
- RBCK1 | c.757-1G>T p.X253_splice (on ENST00000356286 / NM_031229.4; = p.X211_splice on NM_006462.6) | Splice Site (SNP) | VAF 119/523 reads (23%) | called by muse, varscan2
- NKAP | c.936T>A p.A312= | Silent (SNP) | VAF 65/436 reads (15%) | called by muse, mutect2, varscan2
- AL450447.1 | n.137C>T | RNA (SNP) | VAF 76/838 reads (9%) | catalogued as rs1346324428; called by muse, mutect2
